Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A932, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A932-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

MRN:

DOB:

Gender:m

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: thymus, thymoma stitch right pleura

ICD 3
Thymoma, type B2, malignant
8584/3
Site Thymus C379
JW 4/2/14

DIAGNOSIS

1. Thymus, resection (thymus with portion of right pleura):
- a) Thymoma, WHO B2 type (see Comment), with:
- i) Greatest dimension = 5.5 cm
- ii) Multifocal microscopic transcapsular invasion present
- iii) Pleural and lymphovascular invasion not identified
- iv) Resection margins negative for tumor
- b) Thymic tissue with involutional changes
- c) One parathyroid gland without significant abnormality

SYNOPTIC DATA

Specimen Type:	Not specified
Tumor Site:	Thymus
Tumor Size:	Greatest dimension: 5.5 cm
Histologic Type:	Type B thymoma, B2 (cortical)
Pathologic Staging:	Stage IIa: Microscopic transcapsular invasion
Regional Lymph Nodes:	pNX: Cannot be assessed
Distant Metastasis:	Cannot be assessed
Margins:	Margins uninvolved by tumor
Pleural Invasion:	Absent

COMMENT

Sections show a tumor composed of a roughly equal admixture of thymic cortical-type epithelial cells and small lymphocytes. The tumor is

[page 2 of 2]
Department of Pathology

Patient Name

MRN:

DOB:

Gender:M

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

partially encapsulated and microscopically demonstrates several foci of transcapsular invasion into the adjacent fat. The tumor is adherent to a portion of pleura, but pleural invasion is not identified. The tumor appears to have been completely excised. By immunohistochemistry, the epithelial cells stain positive for cytokeratin (AE1/AE3) and P63 and negative for CD5. The small lymphocytes stain positive for CD5, CD1a, and TdT. The overall findings are of a WHO type B2 thymoma, modified Masaoka stage IIa, completely excised.

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

myasthenia gravis

GROSS DESCRIPTION

The specimen is labeled with the patient's name and as "thymus, thymoma stitch right pleura". It consists of a thymus with stitch designating right pleura. It weighs 36 g and measures 10 x 9 x 1.6 cm. It is painted with silver nitrate. On sectioning there is a yellow nodular solid lesion measuring 5.5 x 2.6 x 1.6 cm. A possible portion of pleural tissue marked by a suture is noted, measuring 3x2cm and adherent to the tumor. Representative sections are submitted.

1A-1E tumor with adherent pleura

1F-1J thymic tissue right side

1K-1O thymic tissue left side

Status: complete

Source: NCI Genomic Data Commons file 2f3734d5-594c-4f3d-9663-2545187c868f (TCGA-XU-A932.EEAC2D49-4166-4A70-A399-4376DA12A5FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).